Somatic mutation profile of tumor specimen MP2PRT-PATXVA-TMP1-A (aliquot MP2PRT-PATXVA-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PATXVA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (922 days).
Specimen MP2PRT-PATXVA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ff16abe-3f91-4d92-b6f0-99502cec8388.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATXVA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATXVA-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bd01ecd-9c4f-480a-a6ed-0cd3cb4fda57

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK3 | c.11381C>T p.S3794F | Missense Mutation (SNP) | VAF 17/381 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV55054127; called by muse, mutect2
- ARID1A | c.6661C>T p.P2221S | Missense Mutation (SNP) | VAF 298/882 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs762698084; called by muse, mutect2, varscan2
- CACNA2D1 | c.1789G>C p.E597Q (on ENST00000356253 / NM_001366867.1; = p.E578Q on NM_000722.4) | Missense Mutation (SNP) | VAF 13/311 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.709); catalogued as COSV100666277; called by muse, mutect2
- CLEC14A | c.681C>G p.I227M | Missense Mutation (SNP) | VAF 25/792 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.382); catalogued as COSV60563388; called by muse, mutect2
- HS6ST2 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 28/571 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1336486158; called by muse, mutect2
- KLLN | c.182T>C p.F61S | Missense Mutation (SNP) | VAF 54/748 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs569894367; called by muse, mutect2
- SATL1 | c.650C>G p.S217* (on ENST00000395409; = p.S404* on NM_001012980.2) | Nonsense Mutation (SNP) | VAF 32/466 reads (7%) | catalogued as COSV60576628; called by muse, mutect2
- ZBTB17 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 96/1126 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs1350046192, COSV65270496; called by muse, mutect2
- DOCK5 | c.1264G>C p.D422H | Missense Mutation (SNP) | VAF 42/380 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- MYH3 | c.5341G>C p.E1781Q | Missense Mutation (SNP) | VAF 72/715 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.562); called by muse, mutect2
- POLN | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2
- SCIN | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM71 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 25/683 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.211); called by muse, mutect2
- TRIML1 | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 27/526 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.197); called by muse, mutect2
- TTLL11 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UBA2 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 86/612 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZNF287 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 56/524 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTRT3 | c.492C>T p.I164= | Silent (SNP) | VAF 22/678 reads (3%) | called by muse, mutect2
- H3C4 | c.237C>T p.F79= | Silent (SNP) | VAF 55/593 reads (9%) | catalogued as rs557343198; called by muse, mutect2
- KIAA1109 | c.10491C>T p.D3497= | Silent (SNP) | VAF 19/564 reads (3%) | called by muse, mutect2
- OR8K5 | c.372G>T p.V124= | Silent (SNP) | VAF 57/555 reads (10%) | called by muse, mutect2, varscan2
- SOCS2 | c.111G>T p.A37= | Silent (SNP) | VAF 30/1084 reads (3%) | called by muse, mutect2
- VWA8 | c.3750G>A p.L1250= | Silent (SNP) | VAF 25/382 reads (7%) | called by muse, mutect2
- ZFHX3 | c.5472G>A p.L1824= | Silent (SNP) | VAF 19/559 reads (3%) | called by muse, mutect2
